Somatic mutation profile of tumor specimen TCGA-BF-A1PX-01A (aliquot TCGA-BF-A1PX-01A-12D-A19A-08) from TCGA case TCGA-BF-A1PX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 56.5 years (20,626 days).
Specimen TCGA-BF-A1PX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff86e0f-b40c-4414-8137-117b993a231b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A1PX-10A (Blood Derived Normal), aliquot TCGA-BF-A1PX-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d913ab1-ef3b-44c2-add6-b9cd011c7ff4

The open-access MAF lists 373 somatic variants for this specimen: 236 protein-altering or splice-affecting, 128 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 128, Nonsense Mutation 15, RNA 4, Intron 3, Splice Region 3, Splice Site 2, 3'Flank 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAMP | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV50307176, COSV50307203; called by muse, mutect2, varscan2
- ABCA9 | c.4250C>T p.P1417L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV60622876; called by muse, mutect2
- ACR | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.116); catalogued as rs368710046, COSV53360743; called by mutect2, varscan2
- ADAM20 | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV56454521; called by muse, mutect2, varscan2
- ADAM30 | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 58/563 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV65560715; called by muse, mutect2
- ADAMTSL3 | c.3596G>A p.G1199E | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54442353; called by muse, mutect2, varscan2
- ADGRB3 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65390348; called by muse, mutect2, varscan2
- ADGRL4 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); catalogued as COSV66060844; called by muse, mutect2, varscan2
- ADRA1A | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs368862425; called by muse, mutect2, varscan2
- AHNAK2 | c.6274G>A p.D2092N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV60911852; called by muse, mutect2, varscan2
- ALDH7A1 | c.709G>T p.V237F | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68628871; called by muse, mutect2, varscan2
- ALKBH2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV54356957; called by muse, mutect2, varscan2
- ANGPTL2 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV52219420; called by muse, mutect2, varscan2
- ANKRD50 | c.3569C>T p.S1190L | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV72385344; called by muse, mutect2, varscan2
- ARHGEF17 | c.5104C>T p.P1702S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.027); catalogued as COSV55231187; called by muse, mutect2
- ATP10D | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV56705721; called by muse, mutect2, varscan2
- ATP13A4 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55070269; called by muse, mutect2
- AXDND1 | c.2319G>A p.M773I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs202135298; called by mutect2, varscan2
- BAZ2B | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV100600758; called by muse, mutect2
- BBS7 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV52659692; called by muse, mutect2
- BCAM | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54301443; called by muse, mutect2, varscan2
- BRINP3 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66516979, COSV66528956; called by muse, mutect2, varscan2
- BRWD3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64746047; called by muse, mutect2, varscan2
- BTNL8 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.111); catalogued as rs139672035; called by muse, mutect2, varscan2
- C14orf39 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1305335490, COSV58780862; called by muse, mutect2
- C1QTNF9B | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65943993; called by muse, mutect2, varscan2
- CATSPERB | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99831421; called by muse, mutect2, varscan2
- CD163L1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.757); catalogued as COSV58013866; called by mutect2, varscan2
- CD164L2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV64995561; called by muse, mutect2, varscan2
- CD244 | c.1084G>A p.E362K (on ENST00000368033 / NM_001166663.2; = p.E357K on NM_016382.4) | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs750269608, COSV54433071; called by mutect2, varscan2
- CDCP1 | c.1344G>A p.W448* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV56104532; called by muse, mutect2
- CDH4 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64648404; called by muse, mutect2
- CEACAM5 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV55751514; called by muse, mutect2, varscan2
- CELF3 | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51882375; called by muse, mutect2, varscan2
- CELSR3 | c.6274C>T p.H2092Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV50844942; called by muse, mutect2
- CENPJ | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as COSV67883232; called by muse, mutect2, varscan2
- CENPN | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.596); catalogued as COSV54729022; called by muse, mutect2, varscan2
- CEP128 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1378764762, COSV53673663; called by muse, mutect2, varscan2
- CER1 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV101097876; called by muse, mutect2
- CFAP54 | c.7828C>T p.L2610F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV61571396, COSV61571517; called by muse, mutect2, varscan2
- CHD5 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52411536; called by muse, mutect2
- CHST4 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV58296757; called by muse, varscan2
- CIBAR2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754145020, COSV73320568; called by muse, mutect2, varscan2
- CNTNAP2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.185); catalogued as COSV62158693; called by mutect2, varscan2
- COBL | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV54342228; called by muse, mutect2, varscan2
- COL4A4 | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs770226190, COSV61630936; called by muse, mutect2, varscan2
- CORIN | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.637); catalogued as COSV56684912, COSV56689184; called by muse, mutect2, varscan2
- CPEB2 | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV52590553; called by muse, mutect2, varscan2
- CRISPLD1 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as COSV51546195; called by muse, mutect2, varscan2
- CRX | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs765302774, COSV55756852; called by muse, mutect2, varscan2
- CRYM | c.795G>A p.G265= | Splice Region (SNP) | VAF 7/56 reads (13%) | catalogued as COSV54830402; called by muse, mutect2, varscan2
- CRYZL1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51676808; called by mutect2, varscan2
- CSMD2 | c.8377G>A p.G2793R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV53909203; called by muse, mutect2
- CXXC5 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as COSV56793463; called by muse, mutect2, varscan2
- CYB5R4 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV100859748, COSV63750520; called by muse, mutect2
- DBN1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as COSV52788555, COSV52790187; called by muse, mutect2, varscan2
- DDHD2 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68157566; called by muse, mutect2, varscan2
- DENND3 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52801763; called by muse, mutect2, varscan2
- DEUP1 | c.62T>C p.L21S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53211060; called by muse, mutect2, varscan2
- DGKB | c.1173A>T p.E391D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV51772237; called by mutect2, varscan2
- DGKG | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV53962021; called by muse, mutect2
- DIXDC1 | c.958G>A p.E320K (on ENST00000440460 / NM_001037954.4; = p.E109K on NM_033425.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as COSV59461529; called by mutect2, varscan2
- DLGAP3 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV52392799; called by muse, mutect2, varscan2
- DNAH10 | c.6926T>C p.V2309A (on ENST00000409039; = p.V2248A on NM_207437.3) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68990910; called by muse, mutect2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by mutect2, varscan2
- EEF2K | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1388789029, COSV53780311; called by muse, varscan2
- EFEMP1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV62615606; called by muse, mutect2, varscan2
- EPO | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as COSV53161254; called by muse, mutect2
- ERCC3 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV53426425; called by muse, mutect2, varscan2
- ERICH3 | c.4405G>A p.G1469R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs1334498469, COSV58603293; called by muse, varscan2
- FAM209A | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV54766553; called by muse, mutect2
- FASTKD5 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs114422732, COSV53905185; called by muse, varscan2
- FAT3 | c.11525G>A p.G3842E | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs746711467, COSV53094184; called by muse, mutect2, varscan2
- FCRL4 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as rs754022335, COSV54861247, COSV99619112; called by mutect2, varscan2
- FFAR4 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV65159863; called by muse, mutect2, varscan2
- FPR1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs146075164; ClinVar: uncertain significance; called by mutect2, varscan2
- FRMPD4 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV66213129; called by muse, varscan2
- GIN1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67536620; called by muse, mutect2, varscan2
- GLYATL1 | c.-42-1G>A | Splice Site (SNP) | VAF 7/88 reads (8%) | catalogued as COSV55608159; called by muse, mutect2
- GPR152 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV56885793; called by muse, mutect2, varscan2
- GRIA4 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200645930, COSV56888826; called by muse, mutect2, varscan2
- GRM8 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); catalogued as COSV58807935; called by muse, mutect2, varscan2
- GRM8 | c.1259A>G p.H420R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV58815953; called by muse, mutect2, varscan2
- GTF2H4 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758320282, COSV52558292; called by mutect2, varscan2
- HABP2 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63636297; called by muse, mutect2, varscan2
- HAO2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs866039470, COSV58038810; called by muse, mutect2, varscan2
- HAO2 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as rs764148838, COSV58038827; called by muse, mutect2, varscan2
- HCRTR2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs1286164930, COSV63793572; called by muse, mutect2, varscan2
- HERC5 | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52038502; called by mutect2, varscan2
- HEY1 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV61232624; called by muse, mutect2, varscan2
- HIVEP1 | c.1790A>G p.Q597R | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV65100178; called by muse, mutect2, varscan2
- HLA-DOA | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168834668, COSV57713867, COSV57715376; called by muse, mutect2, varscan2
- HTR4 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761167553, COSV58792548; called by muse, mutect2, varscan2
- ICA1L | c.125T>C p.L42S | Missense Mutation (SNP) | VAF 69/697 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV64172883; called by muse, mutect2, varscan2
- IDH1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs555882127, COSV61620782; called by mutect2, varscan2
- IGF2 | c.183G>A p.M61I (on ENST00000434045 / NM_001127598.3; = p.M5I on NM_000612.6) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56097870; called by mutect2, varscan2
- IL1R2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV60206622, COSV60208931; called by muse, mutect2
- IL1RAPL2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61149689, COSV61156368; called by muse, mutect2, varscan2
- IL36B | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 6/83 reads (7%) | catalogued as COSV52085380; called by muse, mutect2
- IL36G | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1370717444, COSV52078026; called by muse, mutect2, varscan2
- ILDR1 | c.836C>T p.P279L (on ENST00000344209 / NM_001199799.2; = p.P235L on NM_175924.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.797); catalogued as COSV56549101; called by muse, mutect2
- KAT14 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV66607224; called by muse, mutect2, varscan2
- KCNE1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1256155089, COSV61606463; called by mutect2, varscan2
- KCNH2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764666519, COSV51132535; called by mutect2, varscan2
- KCNH5 | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV59756310; called by muse, mutect2
- KLKB1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.152); catalogued as COSV52994851; called by muse, mutect2, varscan2
- KSR2 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV60371401; called by muse, mutect2, varscan2
- LCA5 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV63970859; called by muse, varscan2
- LILRB4 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54404370; called by muse, mutect2, varscan2
- LUZP4 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV64218638; called by muse, mutect2, varscan2
- LYZL1 | c.561G>A p.W187* (on ENST00000375500; = p.W141* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 14/189 reads (7%) | catalogued as COSV100973651; called by muse, mutect2
- MED13 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67262815; called by mutect2, varscan2
- MGAM | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72074235; called by muse, mutect2
- MKX | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV65391862; called by muse, mutect2
- MOGAT3 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV56173584; called by muse, mutect2, varscan2
- MRAS | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV56670912; called by muse, mutect2, varscan2
- MST1R | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as rs1466774865, COSV56566773; called by muse, varscan2
- MUC16 | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV67456414; called by muse, mutect2, varscan2
- MUC17 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60284355; called by muse, mutect2, varscan2
- MUC17 | c.4358G>A p.G1453E | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as rs766089487, COSV60284363; called by muse, mutect2, varscan2
- MYCBP2 | c.8618C>T p.S2873F (on ENST00000357337; = p.S2911F on NM_015057.5) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV62014274; called by muse, mutect2
- MYSM1 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68977248; called by muse, mutect2, varscan2
- NACA2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs1298768878, COSV101478554, COSV71713152; called by muse, varscan2
- NCKAP1 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs772427539, COSV62940515; called by mutect2, varscan2
- NKAPL | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59197406; called by muse, mutect2, varscan2
- NLGN4Y | c.2339C>T p.T780I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as COSV59295128; called by muse, mutect2, varscan2
- NLRP13 | c.2903G>A p.G968E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61621085; called by mutect2, varscan2
- NLRP13 | c.2902G>A p.G968R | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV61620989; called by mutect2, varscan2
- NOSTRIN | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV58320433; called by muse, mutect2
- NOX3 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV50158266, COSV99343307; called by muse, mutect2
- NR2E3 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58907848; called by muse, mutect2
- NUP210L | c.3979C>T p.L1327F | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55144921; called by muse, mutect2, varscan2
- OR1Q1 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as rs1245062153, COSV52917605; called by muse, mutect2, varscan2
- OR2A14 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1385576362, COSV68718061; called by muse, mutect2, varscan2
- OR2L3 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV63454903, COSV63456194; called by muse, mutect2
- OR5D16 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1206160607, COSV65721599, COSV65722679; called by muse, mutect2
- OR5H1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV63402093; called by muse, mutect2
- OR5H2 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV62350439; called by muse, mutect2, varscan2
- OSBP2 | c.2039G>A p.R680K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.326); catalogued as COSV60245378; called by muse, mutect2, varscan2
- OSM | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as rs1356222524, COSV53160748; called by muse, mutect2, varscan2
- PABPC3 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs768139270, COSV55799030; called by muse, mutect2, varscan2
- PCDH18 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV61267388; called by mutect2, varscan2
- PDHA2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs267600306, COSV54776945; called by mutect2, varscan2
- PENK | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1377419372, COSV59240662, COSV59242614; called by muse, mutect2, varscan2
- PENK | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV59240674; called by muse, mutect2
- PGC | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as rs769813637, COSV57824286; called by mutect2, varscan2
- PHLDB1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV61877408; called by muse, mutect2, varscan2
- PIWIL1 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV55345451; called by muse, mutect2, varscan2
- PLA2G4F | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV51826208; called by muse, mutect2, varscan2
- PLEKHG4B | c.2594A>C p.H865P (on ENST00000283426; = p.H1221P on NM_052909.5) | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV52044447, COSV52045583; called by muse, mutect2
- PLEKHG4B | c.2857G>A p.E953K (on ENST00000283426; = p.E1309K on NM_052909.5) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99360496; called by muse, mutect2
- PLG | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.052); catalogued as rs990943130, COSV57512257; called by muse, mutect2, varscan2
- PNPT1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV53176653; called by muse, mutect2, varscan2
- POLR2G | c.336C>T p.S112= | Splice Region (SNP) | VAF 26/232 reads (11%) | catalogued as rs1337809494, COSV57135037; called by muse, mutect2, varscan2
- PPM1E | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.458); catalogued as rs767591305, COSV57572450; called by muse, mutect2, varscan2
- PPM1H | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV57369682, COSV57372572; called by muse, mutect2
- PPP1R16A | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV52952723; called by muse, mutect2, varscan2
- PPP1R32 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.495); catalogued as COSV58544503; called by muse, mutect2, varscan2
- PPP4R1 | c.2114C>T p.P705L (on ENST00000400556 / NM_001042388.3; = p.P688L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99553665; called by muse, mutect2
- PPP4R1 | c.2113C>T p.P705S (on ENST00000400556 / NM_001042388.3; = p.P688S on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99553666; called by muse, mutect2
- PRAMEF1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV60007733; called by muse, mutect2
- PRDM9 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as COSV57004571; called by muse, mutect2, varscan2
- PRTG | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.193); catalogued as COSV66837430; called by muse, mutect2, varscan2
- PTH2R | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV55915096; called by mutect2, varscan2
- PTPN21 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV60847084; called by muse, varscan2
- ROPN1L | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV56873102; called by muse, mutect2, varscan2
- ROR1 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64285888; called by mutect2, varscan2
- RP1 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs868732610, COSV55112868, COSV55113799; called by muse, mutect2, varscan2
- RRP12 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.281); catalogued as rs1461928749, COSV59666410; called by muse, mutect2, varscan2
- RTN1 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1167406480, COSV50720753; called by mutect2, varscan2
- SACS | c.13451C>T p.A4484V | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66537938; called by muse, mutect2, varscan2
- SAMHD1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.987); catalogued as COSV53428242; called by muse, mutect2, varscan2
- SCN10A | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs201068959, COSV71860875; called by mutect2, varscan2
- SCN11A | c.3093C>G p.S1031R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV56568204; called by mutect2, varscan2
- SCN11A | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs749301699, COSV56568211; called by mutect2, varscan2
- SERPINF2 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV60663966; called by muse, mutect2, varscan2
- SERPINI2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52985325; called by muse, mutect2, varscan2
- SLC12A7 | c.2762T>A p.F921Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53755921; called by mutect2, varscan2
- SLC35F3 | c.671C>T p.A224V (on ENST00000366617 / NM_001300845.1; = p.A293V on NM_173508.4) | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64019010; called by muse, mutect2, varscan2
- SLC38A11 | c.434C>T p.S145L (on ENST00000409149 / NM_001351539.1; = p.S123L on NM_173512.2) | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV58052410; called by muse, mutect2, varscan2
- SLC6A4 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55566020; called by muse, mutect2, varscan2
- SLC8A3 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV100776400, COSV63520178; called by muse, mutect2, varscan2
- SPACA1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52759428; called by muse, mutect2, varscan2
- SPATA18 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54643183; called by mutect2, varscan2
- SPHKAP | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV60874011; called by muse, mutect2
- ST18 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV52489498; called by muse, mutect2, varscan2
- STAT3 | c.2305C>T p.P769S (on ENST00000264657 / NM_001369512.1; = p.P768S on NM_003150.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52885734; called by muse, mutect2, varscan2
- SULF1 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52678049; called by muse, mutect2, varscan2
- SYTL4 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV52166542; called by muse, mutect2, varscan2
- TAS2R38 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 21/175 reads (12%) | catalogued as rs868980985, COSV71885246; called by muse, mutect2, varscan2
- TBC1D10A | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs942613686, COSV53163379; called by muse, mutect2, varscan2
- TBXAS1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV54943135; called by muse, mutect2, varscan2
- TENM4 | c.6922C>T p.H2308Y | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV53619131; called by muse, mutect2, varscan2
- TEX13A | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV61176424; called by muse, mutect2
- TLR7 | c.2536T>C p.S846P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV66123952; called by muse, mutect2, varscan2
- TMEM255A | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59028583; called by muse, varscan2
- TNFRSF8 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV55795571; called by muse, mutect2
- TRIM42 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV53881331; called by muse, mutect2, varscan2
- TRIM55 | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV52545022; called by muse, varscan2
- TTN | c.84626T>A p.I28209N (on ENST00000591111; = p.I20785N on NM_003319.4) | Missense Mutation (SNP) | VAF 22/261 reads (8%) | PolyPhen benign (0.387); catalogued as COSV59969146; called by muse, mutect2, varscan2
- TTN | c.15952G>A p.E5318K (on ENST00000591111; = p.E4391K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/192 reads (9%) | PolyPhen probably damaging (0.994); catalogued as COSV100606488; called by muse, mutect2
- TTN | c.15292G>A p.E5098K (on ENST00000591111; = p.E4171K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | PolyPhen benign (0.003); catalogued as rs761181567, COSV59969182; called by mutect2, varscan2
- TTN | c.14456C>T p.S4819L (on ENST00000591111; = p.S3892L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/229 reads (19%) | PolyPhen possibly damaging (0.452); catalogued as rs764310312, COSV59969202; called by muse, mutect2, varscan2
- TTN | c.2008G>A p.E670K (on ENST00000591111; = p.E624K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | PolyPhen benign (0.199); catalogued as COSV59969220; called by muse, mutect2, varscan2
- TXNL1 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV54178792; called by muse, mutect2, varscan2
- TYROBP | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52887416; called by muse, mutect2, varscan2
- UBAC2 | c.808-1G>A p.X270_splice (on ENST00000403766 / NM_001144072.2; = p.X235_splice on NM_177967.4) | Splice Site (SNP) | VAF 9/90 reads (10%) | catalogued as COSV63118144; called by muse, mutect2, varscan2
- UBAC2 | c.808G>A p.G270R (on ENST00000403766 / NM_001144072.2; = p.G235R on NM_177967.4) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV63119948; called by muse, mutect2, varscan2
- UBASH3A | c.1395G>A p.G465= | Splice Region (SNP) | VAF 10/59 reads (17%) | catalogued as COSV52311515; called by muse, mutect2, varscan2
- UGT2B7 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as COSV59442755; called by muse, mutect2
- UGT3A2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56929472; called by muse, mutect2, varscan2
- UIMC1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV65893339; called by muse, mutect2, varscan2
- UNC13B | c.2468C>T p.T823I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV65933330; called by muse, mutect2, varscan2
- UNC13B | c.4520C>T p.S1507F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.438); catalogued as COSV100266746; called by muse, mutect2, varscan2
- UNC13C | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52858169; called by muse, mutect2, varscan2
- UNC79 | c.671C>T p.S224L (on ENST00000393151 / NM_001346218.2; = p.S47L on NM_020818.5) | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56381265; called by muse, mutect2
- USF3 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV57071279; called by muse, mutect2, varscan2
- VWA3B | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV68241964; called by muse, mutect2
- WIPF1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1430081823, COSV99768887; called by muse, mutect2, varscan2
- XIRP2 | c.3413G>A p.R1138K (on ENST00000628543; = p.R1313K on NM_152381.6) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV54691487, COSV54695312; called by muse, mutect2
- ZBED2 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs1401056102, COSV104368363, COSV51914547; called by mutect2, varscan2
- ZDHHC13 | c.1406A>G p.H469R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV67980681; called by mutect2, varscan2
- ZEB2 | c.3226C>G p.H1076D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57954410; called by muse, mutect2
- ZMIZ2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1409908765, COSV54806875; called by mutect2, varscan2
- ZNF2 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as rs866140356, COSV54636529; called by muse, mutect2, varscan2
- ZNF280A | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV57480028, COSV57480198; called by muse, mutect2
- ZNF287 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 19/190 reads (10%) | catalogued as COSV67688277; called by muse, mutect2, varscan2
- ZNF292 | c.6400C>T p.H2134Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60537367; called by muse, mutect2, varscan2
- ZNF396 | c.110A>T p.D37V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100108584; called by muse, mutect2, varscan2
- ZNF512B | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV53868272; called by muse, mutect2
- ZNF532 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs376845672, COSV100266060; called by mutect2, varscan2
- ZNF662 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs1356344783, COSV60241344; called by mutect2, varscan2
- ZNF804B | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758173687, COSV60822516; called by mutect2, varscan2
- COL4A3 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCOA4 | c.1586C>T p.T529I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, varscan2
- VRK2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by mutect2, varscan2
- ABCA4 | c.2475G>A p.G825= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV64672519; called by muse, mutect2
- ABCC4 | c.975C>T p.F325= | Silent (SNP) | VAF 19/214 reads (9%) | catalogued as COSV65311100; called by muse, mutect2, varscan2
- ADAP2 | c.717C>T p.A239= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV58295519; called by muse, mutect2
- ADGRV1 | c.4191C>T p.S1397= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV67979495; called by muse, mutect2, varscan2
- ALMS1 | c.1269C>T p.V423= | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as COSV52506833; called by mutect2, varscan2
- ALPP | c.975C>T p.P325= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV67396070; called by muse, mutect2
- ANKS1A | c.2259C>T p.L753= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs926962967, COSV64459741; called by mutect2, varscan2
- ARHGAP29 | c.888G>A p.R296= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV53110137; called by muse, mutect2
- ARRDC1 | c.726C>T p.I242= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs113768660, COSV100604004; called by mutect2, varscan2
- ARRDC1 | c.727C>T p.L243= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs1301638626, COSV100604005; called by muse, mutect2, varscan2
- ASPRV1 | c.714C>T p.P238= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100208533; called by muse, mutect2, varscan2
- ATP13A4 | c.3510C>T p.T1170= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV61318316; called by muse, mutect2, varscan2
- ATP8A2 | c.1791G>A p.V597= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV54945281; called by mutect2, varscan2
- ATP8B4 | c.3574C>T p.L1192= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as COSV52712345; called by muse, mutect2, varscan2
- BRD8 | c.1173G>A p.K391= (on ENST00000254900 / NM_139199.2; = p.K464= on NM_006696.4) | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV50146268; called by muse, mutect2
- BRINP1 | c.1882C>T p.L628= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV56296582; called by muse, mutect2, varscan2
- BRPF3 | c.888C>T p.I296= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV60206745; called by muse, mutect2, varscan2
- C2CD3 | c.5784C>T p.D1928= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV58091642; called by muse, mutect2, varscan2
- C2orf16 | c.1119G>A p.E373= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV68645681, COSV68645961; called by muse, mutect2, varscan2
- CACNA2D3 | c.2241C>T p.T747= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV55527266, COSV99874552; called by muse, mutect2, varscan2
- CCDC88C | c.5100C>T p.F1700= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV57796189; called by muse, mutect2, varscan2
- CER1 | c.780C>T p.S260= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs142384565, COSV101097874; called by mutect2, varscan2
- CHD5 | c.5121C>T p.I1707= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs772790386, COSV52411510; called by mutect2, varscan2
- CNGB3 | c.873G>A p.R291= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV60687447; called by muse, mutect2, varscan2
- COLEC10 | c.648G>A p.R216= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV60520895; called by muse, mutect2
- DNAH3 | c.9747C>T p.S3249= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as COSV54513227; called by muse, mutect2, varscan2
- DNAH5 | c.10191A>G p.K3397= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1250972452, COSV54215411; ClinVar: likely benign; called by muse, mutect2
- DNAH9 | c.6954C>T p.F2318= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs368740897, COSV52342150, COSV52344136; called by mutect2, varscan2
- DNM3 | c.2031C>T p.I677= (on ENST00000355305 / NM_001350206.2; = p.I671= on NM_015569.5) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV62455669; called by muse, mutect2, varscan2
- EFCAB3 | c.429C>T p.I143= | Silent (SNP) | VAF 25/154 reads (16%) | catalogued as COSV59500842; called by muse, mutect2, varscan2
- EPHA7 | c.1968G>A p.G656= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as COSV65180377; called by muse, mutect2, varscan2
- EYA2 | c.330C>T p.S110= | Silent (SNP) | VAF 15/157 reads (10%) | catalogued as COSV57940812; called by muse, mutect2, varscan2
- FCF1 | c.504C>T p.I168= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV62044007; called by muse, mutect2
- FGR | c.450G>A p.G150= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV64969392; called by muse, mutect2
- GABRA2 | c.519C>T p.F173= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV62913552; called by muse, mutect2, varscan2
- GLP2R | c.1362C>T p.F454= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV52323474; called by muse, mutect2, varscan2
- GPR65 | c.411C>T p.S137= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs571054746, COSV50862471; called by mutect2, varscan2
- GRIK5 | c.1029G>A p.G343= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV53476777; called by muse, mutect2, varscan2
- GUCY1A2 | c.2016C>T p.F672= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV56482813; called by mutect2, varscan2
- HAVCR1 | c.969G>A p.K323= | Silent (SNP) | VAF 48/296 reads (16%) | catalogued as COSV59398949; called by muse, mutect2, varscan2
- HAX1 | c.66C>T p.P22= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs1368258660, COSV55170536; called by muse, varscan2
- HEPH | c.909C>T p.V303= (on ENST00000343002; = p.V36= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57961337; called by muse, mutect2
- HHLA2 | c.30C>T p.F10= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs765363665, COSV63316578; called by mutect2, varscan2
- HYOU1 | c.1401G>A p.R467= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1370377831, COSV101345623; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.57C>T p.S19= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- ITGB4 | c.4095C>T p.V1365= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV52323635; called by muse, mutect2
- KIF5A | c.1968C>T p.H656= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as rs774039296, COSV99673144; called by mutect2, varscan2
- KIF5A | c.1969C>T p.L657= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV99673147; called by muse, mutect2, varscan2
- ME1 | c.186C>T p.F62= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs748274488, COSV63838212; called by mutect2, varscan2
- MUC16 | c.22818G>A p.R7606= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV67456405, COSV67461702; called by muse, mutect2, varscan2
- MYH6 | c.2574C>T p.F858= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs148596692, COSV62455115; ClinVar: likely benign; called by mutect2, varscan2
- MYH6 | c.2385G>C p.R795= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV62449118; called by muse, mutect2, varscan2
- MYO15A | c.3846G>A p.R1282= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1157425865, COSV52754596; called by muse, mutect2
- NACA2 | c.213G>A p.R71= | Silent (SNP) | VAF 24/216 reads (11%) | catalogued as COSV101478560, COSV71713085; called by muse, mutect2, varscan2
- NCOA1 | c.4278C>T p.T1426= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs778966984, COSV56041831; called by mutect2, varscan2
- NIBAN1 | c.915G>A p.L305= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV62284061; called by muse, mutect2, varscan2
- NLRC3 | c.366C>T p.V122= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs773356010, COSV100072948; called by mutect2, varscan2
- NOX3 | c.294C>T p.N98= | Silent (SNP) | VAF 30/364 reads (8%) | catalogued as COSV50153657, COSV99343309; called by muse, mutect2
- NPAS4 | c.1581C>T p.A527= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs1483347403, COSV100215074; called by muse, mutect2
- OR10A5 | c.279C>T p.I93= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs748445061, COSV55053699, COSV55054729; called by mutect2, varscan2
- OR10S1 | c.930G>A p.K310= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1384306313, COSV73342697; called by muse, mutect2, varscan2
- OR10W1 | c.312C>T p.F104= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV67720335; called by muse, mutect2, varscan2
- OR1C1 | c.768C>T p.I256= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs267598481, COSV68715593; called by mutect2, varscan2
- OR1E1 | c.75C>T p.N25= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs751898297, COSV59458718; called by muse, mutect2, varscan2
- OR2A2 | c.678G>A p.K226= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV68871330; called by muse, mutect2, varscan2
- OR2W1 | c.684G>A p.T228= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs144276666, COSV65851448; called by mutect2, varscan2
- OR4C15 | c.364C>T p.L122= (on ENST00000314644; = p.L68= on NM_001001920.2) | Silent (SNP) | VAF 20/178 reads (11%) | catalogued as COSV58951975; called by muse, mutect2, varscan2
- OR4K5 | c.118C>T p.L40= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV60002907; called by muse, mutect2, varscan2
- OR4N2 | c.174C>T p.P58= | Silent (SNP) | VAF 28/262 reads (11%) | catalogued as COSV60050735, COSV60053997; called by muse, varscan2
- OR4Q3 | c.282C>T p.F94= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV59177427; called by muse, varscan2
- OR56A3 | c.186C>T p.P62= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV61568771; called by muse, mutect2, varscan2
- OR5AK2 | c.27C>T p.V9= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as rs765906761, COSV58804194; called by muse, mutect2, varscan2
- OR5AS1 | c.729C>T p.S243= | Silent (SNP) | VAF 21/168 reads (13%) | catalogued as COSV57981352; called by muse, mutect2, varscan2
- OR8A1 | c.843C>T p.I281= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs749600725, COSV52508300; called by mutect2, varscan2
- OR8B12 | c.264G>A p.K88= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV60911455; called by muse, mutect2
- OVGP1 | c.1749C>T p.V583= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs1384308259, COSV63858085; called by mutect2, varscan2
- PCNX4 | c.2649C>T p.Y883= (on ENST00000406854 / NM_001330177.2; = p.Y649= on NM_022495.5) | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as rs1383233298, COSV58303150; called by muse, mutect2, varscan2
- PIWIL4 | c.2268G>A p.V756= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs1385386233, COSV54408692; called by muse, mutect2, varscan2
- PLEKHG4B | c.2856G>A p.K952= (on ENST00000283426; = p.K1308= on NM_052909.5) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99360492; called by muse, mutect2
- PNPO | c.309G>A p.G103= | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as COSV56666220; called by muse, mutect2, varscan2
- PODN | c.807C>T p.V269= (on ENST00000395871; = p.V221= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV57012261; called by muse, mutect2, varscan2
- POLE | c.3441C>T p.I1147= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs748278223, COSV57677399; ClinVar: likely benign; called by mutect2, varscan2
- PRDX5 | c.219G>A p.G73= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV50005138; called by muse, mutect2, varscan2
- PSG3 | c.1140T>C p.F380= | Silent (SNP) | VAF 23/226 reads (10%) | catalogued as COSV59503386; called by muse, mutect2, varscan2
- PTCD2 | c.183G>A p.K61= | Silent (SNP) | VAF 31/246 reads (13%) | catalogued as COSV54649583; called by muse, mutect2, varscan2
- PTPN13 | c.3819C>T p.T1273= (on ENST00000411767 / NM_080683.3; = p.T1254= on NM_006264.3) | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV57404918; called by muse, mutect2
- R3HDM1 | c.729G>A p.K243= | Silent (SNP) | VAF 23/201 reads (11%) | catalogued as COSV51522773; called by muse, mutect2, varscan2
- RAPGEF5 | c.789G>A p.R263= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV59780716; called by muse, mutect2, varscan2
- RNF133 | c.327T>C p.G109= | Silent (SNP) | VAF 13/162 reads (8%) | catalogued as COSV57356680; called by muse, mutect2
- RREB1 | c.4683C>T p.I1561= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs374502214; called by mutect2, varscan2
- RSPH6A | c.1218C>T p.S406= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs868846073, COSV55571000; called by muse, mutect2
- SCN11A | c.1398G>A p.R466= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV56568221; called by muse, mutect2, varscan2
- SCN9A | c.1941G>A p.E647= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1474457454, COSV57605285, COSV57617143; called by muse, mutect2, varscan2
- SEMA6C | c.720C>T p.F240= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100501374; called by muse, mutect2, varscan2
- SERPINB7 | c.886C>T p.L296= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV60532632, COSV60533223; called by muse, mutect2
- SMPD2 | c.246C>T p.L82= | Silent (SNP) | VAF 39/245 reads (16%) | catalogued as COSV57804764; called by muse, mutect2, varscan2
- SPHKAP | c.535C>T p.L179= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV60874023; called by muse, mutect2, varscan2
- SREBF2 | c.1210C>T p.L404= | Silent (SNP) | VAF 33/228 reads (14%) | catalogued as rs781489533, COSV63330835; called by muse, mutect2, varscan2
- ST3GAL3 | c.372C>T p.F124= (on ENST00000361392 / NM_174964.4; = p.F109= on NM_006279.5) | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as COSV99495565; called by muse, mutect2, varscan2
- ST3GAL3 | c.373C>T p.L125= (on ENST00000361392 / NM_174964.4; = p.L110= on NM_006279.5) | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as COSV99495568; called by muse, mutect2, varscan2
- STAB2 | c.4617C>T p.A1539= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as COSV66337078; called by muse, mutect2
- SULF2 | c.1731G>A p.K577= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV63415110; called by muse, varscan2
- SZT2 | c.4872C>T p.P1624= (on ENST00000634258 / NM_001365999.1; = p.P1567= on NM_015284.4) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs766275248, COSV65168535; called by mutect2, varscan2
- TAAR9 | c.222G>A p.L74= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV71512210, COSV71512285; called by muse, mutect2
- TAGAP | c.1281C>T p.F427= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV57851048; called by muse, mutect2, varscan2
- TDRD5 | c.1941C>T p.F647= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV54240874; called by muse, mutect2, varscan2
- TRIM55 | c.1440G>A p.R480= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV52545036; called by muse, varscan2
- TRIT1 | c.966C>T p.A322= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100381592; called by muse, mutect2
- TTBK1 | c.219C>T p.V73= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV52489734; called by muse, mutect2, varscan2
- TTC7A | c.2223C>T p.F741= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs548516149, COSV55409876; called by muse, mutect2, varscan2
- TTN | c.88053G>A p.G29351= (on ENST00000591111; = p.G21927= on NM_003319.4) | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV59969110; called by muse, mutect2, varscan2
- UGT2B28 | c.1077G>A p.Q359= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59431333; called by muse, mutect2, varscan2
- UNC13C | c.1329G>A p.K443= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as rs1163181207, COSV52858204; called by muse, varscan2
- VHLL | c.403C>T p.L135= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as COSV60554273; called by muse, mutect2, varscan2
- VSIG10 | c.721T>C p.L241= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV63652657; called by muse, mutect2, varscan2
- VWA7 | c.711G>A p.P237= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs1304860985, COSV63304401, COSV63304796; called by muse, mutect2
- VWA8 | c.5667C>T p.I1889= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV64995043; called by muse, mutect2, varscan2
- WIF1 | c.252C>T p.I84= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV54130689; called by muse, mutect2, varscan2
- WSCD1 | c.1710G>A p.R570= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV58494737; called by muse, mutect2, varscan2
- ZBTB18 | c.805C>T p.L269= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100700122, COSV62396617; called by mutect2, varscan2
- ZBTB7C | c.615G>A p.R205= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV59688168; called by muse, mutect2, varscan2
- ZIM3 | c.1230G>A p.Q410= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as COSV54141367; called by muse, mutect2
- ZNF229 | c.333G>A p.E111= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1173440669, COSV52160881; called by muse, mutect2, varscan2
- ZNF382 | c.156G>A p.K52= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV53087166; called by muse, varscan2
- ZNF585B | c.1062C>T p.S354= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as rs1327707487, COSV57214961; called by muse, mutect2, varscan2
- ZNF831 | c.4839G>A p.R1613= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV64038823; called by muse, mutect2
- ZNFX1 | c.2982C>T p.I994= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as COSV65574585; called by muse, mutect2
- ZSCAN31 | c.999C>T p.L333= | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as rs754959278, COSV60180566; called by muse, mutect2
- AC016747.4 | n.502G>A | RNA (SNP) | VAF 9/47 reads (19%) | catalogued as COSV54373989; called by mutect2, varscan2
- EPHA10 | c.850+24G>T | Intron (SNP) | VAF 15/72 reads (21%) | catalogued as rs778610760, COSV100140000; called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888367 G>A | 3'Flank (SNP) | VAF 14/56 reads (25%) | catalogued as COSV58044761; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5273C>T | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as COSV61087428; called by muse, varscan2
- OR2U1P | n.630C>T | RNA (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2
- SKAP1 | c.978+5976T>C | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100411983; called by muse, mutect2, varscan2
- SNORD116-1 | n.17C>T | RNA (SNP) | VAF 8/88 reads (9%) | catalogued as rs1023512620; called by muse, mutect2
- TMEM99 | n.896C>T | RNA (SNP) | VAF 8/70 reads (11%) | catalogued as rs1307503370, COSV56982330; called by mutect2, varscan2
- Unknown | chr21:16194598 C>A | IGR (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
